CPTAC case C3L-02954 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81df2de0-6770-4d6f-a656-3ed96cb1327c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1965; Vital status: Dead; Days to death: 637 days (1.7 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 52.5 years (19,171 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 637 days (1.7 years); Progression or recurrence: yes; Days to last follow up: 632 days (1.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 10 cm); Lymph node involvement: Positive; Lymph nodes positive: 8; Lymph nodes tested: 15; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 267 days; Disease response: With Tumor.
- Days to follow up: 632 days (1.7 years); Disease response: With Tumor.
- Days to follow up: 632 days (1.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 240 days.

Other clinical attributes
- Weight: 128 kg; Height: 170 cm; BMI: 44.29; DLCO (% of predicted): 71; FEV1/FVC after bronchodilator (%): 68; FEV1/FVC before bronchodilator (%): 71; FEV1 after bronchodilator (% of reference): 81; FEV1 before bronchodilator (% of reference): 96.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 39; Cigarettes per day: 20; Tobacco smoking onset year: 1978; Tobacco smoking quit year: 2017; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 39.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02954-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 225 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02954-21: Section location: Left Upper Lobe; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-02954-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 361 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02954-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
